Somatic mutation profile of tumor specimen MP2PRT-PAVSAG-TMP1-A (aliquot MP2PRT-PAVSAG-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVSAG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (988 days).
Specimen MP2PRT-PAVSAG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 678f1244-5d13-4c0c-a312-c12337d4d7d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVSAG-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVSAG-NM1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18f6c357-5a55-4aef-bd32-3b999b88a69f

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 6, Silent 5, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IL17RC | c.1123G>A p.A375T (on ENST00000295981 / NM_153461.4; = p.A289T on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.013); catalogued as rs758390328, COSV55972878; called by muse, mutect2
- LHCGR | c.1354C>A p.L452I | Missense Mutation (SNP) | VAF 110/249 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99683085; called by muse, mutect2, varscan2
- MMP25 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 197/463 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs1334779412; called by muse, mutect2, varscan2
- PHLDB1 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as rs372763753; called by muse, mutect2
- SYVN1 | c.465C>A p.F155L | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.048); catalogued as COSV53695522; called by muse, mutect2, varscan2
- TACC2 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 36/496 reads (7%) | catalogued as rs377057058; called by muse, mutect2
- COPS2 | c.555del p.D186Mfs*3 | Frame Shift Del (DEL) | VAF 22/69 reads (32%) | called by mutect2, pindel, varscan2
- HLA-DPB1 | c.364+6_364+9del p.X122_splice | Splice Site (DEL) | VAF 93/362 reads (26%) | called by pindel, varscan2
- PDZD4 | c.1095C>A p.C365* | Nonsense Mutation (SNP) | VAF 61/852 reads (7%) | called by muse, mutect2
- PIGH | c.497G>A p.C166Y | Missense Mutation (SNP) | VAF 78/278 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); called by muse, varscan2
- DMBT1 | c.2340G>A p.T780= | Silent (SNP) | VAF 45/684 reads (7%) | catalogued as rs761013722, COSV57540963; called by muse, mutect2
- GPR37 | c.1686G>A p.E562= | Silent (SNP) | VAF 149/336 reads (44%) | catalogued as rs375447551; called by muse, mutect2, varscan2
- NOTCH1 | c.1374G>A p.S458= | Silent (SNP) | VAF 46/431 reads (11%) | catalogued as rs886039016, COSV53045958; ClinVar: likely benign; called by muse, mutect2, varscan2
- NYX | c.972C>T p.P324= | Silent (SNP) | VAF 222/799 reads (28%) | catalogued as rs1303341110; called by muse, varscan2
- PHLDB1 | c.1054C>T p.L352= | Silent (SNP) | VAF 32/477 reads (7%) | called by muse, mutect2
